Gene-level copy-number profile of tumor specimen TCGA-78-7146-01A from TCGA case TCGA-78-7146, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 71.9 years (26,272 days).
Specimen TCGA-78-7146-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.ce4a72a2-7d07-4a24-8d49-42f1d75271be.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-78-7146-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dcf57d55-04f9-4c35-b6a6-194edf2e1713

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,923; copy number 2: 26,712; copy number 3: 22,060; copy number 4: 3,835; copy number 5: 2,667; copy number 6: 1,249; copy number 7: 667; copy number 8: 189; copy number 9: 256; copy number 10: 11; copy number 11: 195; copy number 17: 6; copy number 18: 1; copy number 19: 38; copy number 20: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-78-7146-01A-11D-2035-01): tumor purity 0.68, ploidy 2.79, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,281 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,146,203–149,556,361, 105 genes, copy number 6–20 (within-gene range 3–20) (broad region; genes not listed).
- chr1:150,809,713–150,876,708, 1 gene, copy number 7 (within-gene range 4–7): ARNT.
- chr1:150,881,236–156,677,407, 344 genes, copy number 7 (broad region; genes not listed).
- chr1:159,062,484–165,911,618, 214 genes, copy number 6–11 (broad region; genes not listed).
- chr1:168,178,962–168,263,481, 6 genes, copy number 7: TIPRL, RPL34P1, AL021397.1, SFT2D2, ANKRD36BP1, RNU6-1310P.
- chr2:127,888,829–130,776,957, 91 genes, copy number 5 (broad region; genes not listed).
- chr2:134,838,616–134,902,034, 1 gene, copy number 5 (within-gene range 4–5): ACMSD.
- chr2:134,918,235–140,221,485, 56 genes, copy number 5: CCNT2, MAP3K19, RAB3GAP1, SNORA40B, ZRANB3, G3BP1P1, R3HDM1, RNU6-512P, MIR128-1, UBXN4, LCT, Y_RNA, LCT-AS1, MCM6, MANEALP1, DARS1, DARS-AS1, AC068492.1, CXCR4, HNRNPKP2, AC112255.1, UBBP1, RN7SKP141, SMC4P1, THSD7B, RNA5SP105, Y_RNA, HNMT, LINC01832, RPL15P5, YWHAEP5, IDI1P1, RNF14P1, AC114763.1, AC114763.2, SPOPL, AC092620.1, AC092620.2, LINC02631, NXPH2, RN7SKP286, YY1P2, AHCYP4, AC023468.1, AC013265.1, AC062021.1, AC016710.1, SNORA72, MRPS18BP2, RPL9P13, AC078851.1, RN7SL283P, LINC01853, MTCO1P44, MTND2P19, MTND1P27.
- chr2:140,234,737–140,683,888, 3 genes, copy number 5: AC092156.1, MIR7157, COPRSP1.
- chr3:91,356,755–198,222,513, 1,802 genes, copy number 5–9 (within-gene range 1–9) (broad region; genes not listed).
- chr7:54,185,071–54,257,577, 1 gene, copy number 5 (within-gene range 3–5): AC092848.2.
- chr7:54,330,670–62,275,678, 156 genes, copy number 5 (broad region; genes not listed).
- chr7:92,412,550–102,679,295, 306 genes, copy number 7–9 (within-gene range 3–9) (broad region; genes not listed).
- chr8:46,784,800–145,066,685, 1,529 genes, copy number 5–6 (broad region; genes not listed).
- chr10:42,149,310–43,981,102, 64 genes, copy number 5 (broad region; genes not listed).
- chr10:46,549,044–55,627,942, 138 genes, copy number 7–10 (within-gene range 3–10) (broad region; genes not listed).
- chr10:56,595,963–58,399,220, 13 genes, copy number 6–11: AC025039.1, MIR3924, AL731534.1, AC006484.1, MRPS35P3, AC026884.1, IPMK, TPT1P10, CISD1, AC016396.1, AC016396.2, UBE2D1, TFAM.
- chr11:128,614,340–135,075,908, 101 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:68,746,125–72,186,618, 67 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr12:75,391,089–75,984,015, 14 genes, copy number 5: GLIPR1L2, GLIPR1, AC121761.1, KRR1, AC078923.1, AC022507.1, AC078820.2, RPL10P13, SNORA70, AC078820.1, AC011611.6, RN7SL734P, AC011611.2, AC011611.1.
- chr16:70,802,084–71,230,722, 4 genes, copy number 7 (within-gene range 2–7): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.
- chr17:36,544,912–37,406,836, 21 genes, copy number 5 (within-gene range 3–5): GGNBP2, AC243732.1, DHRS11, MRM1, AC243830.2, AC243830.3, AC243830.1, LHX1-DT, LHX1, AC243773.1, AATF, AC243773.2, AC244093.4, MIR2909, AC244093.3, AC244093.5, ACACA, AC244093.1, HMGB1P24, AC244093.2, C17orf78.
- chr17:61,590,421–64,263,260, 95 genes, copy number 5–11 (broad region; genes not listed).
- chr17:65,635,537–66,192,133, 1 gene, copy number 7 (within-gene range 4–7): CEP112.
- chr17:66,197,693–70,629,265, 100 genes, copy number 5–11 (broad region; genes not listed).
- chr17:73,067,870–73,663,848, 15 genes, copy number 5: ATG12P1, POLR3KP2, AC097641.1, SSTR2, COG1, AC097641.2, FAM104A, C17orf80, AC087301.1, CPSF4L, CDC42EP4, SDK2, AC124804.1, AC032019.1, AC032019.2.
- chr17:74,043,452–74,262,020, 5 genes, copy number 6 (within-gene range 1–6): LINC02074, RPL38, MGC16275, TTYH2, AC100786.1.
- chr17:78,423,697–78,782,297, 8 genes, copy number 6 (within-gene range 1–6): DNAH17, DNAH17-AS1, AC016182.1, RN7SL454P, SCAT1, CYTH1, AC099804.1, RNU6-638P.
- chr17:82,371,400–82,648,553, 20 genes, copy number 7 (within-gene range 3–7): UTS2R, AC132938.1, OGFOD3, AC132938.2, Y_RNA, HEXD, HEXD-IT1, CYBC1, AC132938.6, AC132938.3, NARF, AC132938.5, NARF-AS1, NARF-IT1, FOXK2, AC124283.4, AC124283.3, AC124283.2, AC124283.1, WDR45B.

Autosomal genes at a single copy (total copy number 1): 1,858. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
